Somatic mutation profile of tumor specimen MP2PRT-PARULA-TMP1-C (aliquot MP2PRT-PARULA-TMP1-C-1-0-D-A83C-36) from MP2PRT case MP2PRT-PARULA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.9 years (4,354 days).
Specimen MP2PRT-PARULA-TMP1-C: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2de0b6ee-d557-4207-a5a4-5b28bbc81a27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARULA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARULA-NB1-A-1-0-D-A83C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee5f595a-7dca-4899-b4e1-0aa64ce95ca2

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, RNA 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM2 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 53/229 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768627777, COSV55868561; called by muse, mutect2, varscan2
- BEST3 | c.1289G>T p.S430I | Missense Mutation (SNP) | VAF 22/670 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.136); catalogued as COSV100437856; called by muse, mutect2
- CTNND2 | c.1876G>A p.D626N | Missense Mutation (SNP) | VAF 91/473 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781670382, COSV58938331; called by muse, mutect2, varscan2
- GDF7 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 28/654 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55347639; called by muse, mutect2
- KBTBD13 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 174/572 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs750168932; called by muse, mutect2, varscan2
- SLC4A11 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 141/373 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.081); catalogued as rs752287261, CM081815, COSV66261292; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNAI3 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 110/380 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761104309; called by muse, mutect2, varscan2
- ETV6 | c.1073_1074dup p.R359Sfs*13 | Frame Shift Ins (INS) | VAF 103/327 reads (31%) | called by mutect2, pindel, varscan2
- KLHDC7A | c.1978G>A p.G660S | Missense Mutation (SNP) | VAF 201/480 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR10V1 | c.815G>A p.G272D | Missense Mutation (SNP) | VAF 103/482 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PAXIP1 | c.2017A>G p.T673A | Missense Mutation (SNP) | VAF 17/286 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLCO6A1 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 25/563 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- TRDD3 | chr14:22449080 del GGGGAAGTTTTTGTAAAGCTCTGTAGCACTGTGACTG | Missense Mutation (DEL) | VAF 10/76 reads (13%) | called by mutect2, pindel
- FAM83A | c.1170C>T p.H390= | Silent (SNP) | VAF 34/1124 reads (3%) | called by muse, mutect2
- GLDN | c.72G>A p.A24= | Silent (SNP) | VAF 32/671 reads (5%) | called by muse, mutect2
- KIR3DL3 | c.1161C>T p.C387= | Silent (SNP) | VAF 151/426 reads (35%) | catalogued as rs746405337, COSV99400169; called by muse, mutect2, varscan2
- DCHS2 | n.664C>T | RNA (SNP) | VAF 94/374 reads (25%) | catalogued as rs756567652, COSV59718576; called by muse, mutect2, varscan2
- OR7E19P | n.249T>G | RNA (SNP) | VAF 18/354 reads (5%) | called by muse, mutect2
